Surgical pathology report (de-identified scan), TCGA case TCGA-P3-A5QA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site  Fred Hutchinson, specimen TCGA-P3-A5QA-01A (Primary Tumor).

[page 1 of 2]
TSS Unique Patient #

COLLECTED:

EC0-0-3
Carcinoma, squamous cell NO:
807013
Site Tongue NOS CO2.9
JW 4/12/13

CLINICAL DATA: Tongue CA. Partial glossectomy.

GROSS DESCRIPTION: A) Received in formalin labeled " ", and designated "right partial glossectomy, single stitch = anterior, double stitch = medial" is a 4.3 cm AP x 3.6 cm ML x 2.2 cm SI partial glossectomy specimen with a single long suture on one aspect and a double suture at 90%. The single suture is arbitrarily designated 6 o'clock/anterior, and the double stitch is arbitrarily designated 3 o'clock/medial. Gross photographs are taken. The mucosal aspect measures 4.2 cm AP x 2.6 cm ML and is resected on an irregular plane on the lateral side. Centrally located is a 1.6 x 0.9 x up to 0.8 cm deep ulcer, located grossly 0.4 cm from the lateral mucosal resection margin at approximately 9 o'clock. The specimen is inked as follows: 12 o'clock to 3 o'clock - black; 3 o'clock to 6 o'clock - red; 6 o'clock to 9 o'clock - blue; 9 o'clock to 12 o'clock - green. The specimen is sectioned from posterior to anterior and a 2.7 cm AP x 1.8 cm ML x approximately 1.2 cm SI, white, firm lesion is identified. The lesion comes to within 0.2 cm of the deep margin at approximately 9:30-10 o'clock. It comes to within 0.3 cm of the blue mucosal margin at approximately 6:30-7 o'clock, 0.5 cm of the red mucosal margin at approximately 4 o'clock, 0.8 cm from the green mucosal margin at approximately 11 o'clock, and is approximately 1 cm from the closest black mucosal margin; Cassette summary: A1 - deepest extent of tumor, complete cross-section; A2 - closest blue mucosal margin and closest red mucosal margin; A3 - suspicious small nodule midline at approximately 3 o'clock/9 o'clock; A4 - closest green and closest black mucosal margin. B) The specimen was received fresh in the frozen section room labeled with " ", is designated "frozen anterior", and consists of a 0.5 x 0.4 x 0.2 cm portion of white/pink soft tissue with a possible mucosal surface. The specimen is inked blue and entirely submitted for intraoperative evaluation. The frozen section remnant is submitted in its entirety in cassette B/C/DFS1. C) The specimen was received fresh in the frozen section room labeled with " ", is designated "frozen lateral", and consists of a 0.4 x 0.4 x 0.2 cm portion of white/pink soft tissue with a possible mucosal surface. The specimen is inked black and entirely submitted for intraoperative evaluation. The frozen section remnant is submitted in its entirety in cassette B/C/DFS1. D) The specimen was received fresh in the frozen section room labeled with " ", and is designated "frozen posterior", and consists of a 0.3 x 0.2 x 0.2 cm portion of white/pink soft tissue with a possible mucosal surface. The specimen is inked red and entirely submitted for intraoperative evaluation. The frozen section remnant is submitted in its entirety in cassette B/C/DFS1. E) The specimen was received fresh in the frozen section room labeled with " ", is designated "frozen medial", and was received in two parts: the first part contained a scant fragment of tissue which appeared cauterized and would not survive processing, so a second portion of tissue was submitted for part E. This tissue measures 0.6 x 0.4 x 0.4 cm, and has a white, verrucous appearing surface. The specimen is inked red and entirely submitted for intraoperative evaluation. The frozen section remnant is submitted in its entirety in cassette E/F/GFS1. F) The specimen was received fresh in the frozen section room labeled with " ", is designated "frozen anterior deep", and consists of a 0.5 x 0.3 x 0.3 cm portion of skeletal muscle. The specimen is inked black and entirely submitted for intraoperative evaluation. The frozen section remnant is submitted in its entirety in cassette E/F/GFS1. G) The specimen was received fresh in the frozen section room labeled with " ", is designated "frozen posterior deep", and consists of a 0.7 x 0.6 x 0.4 cm portion of skeletal muscle. The specimen was inked blue and

[page 2 of 2]
entirely submitted for intraoperative evaluation. The frozen section remnant is submitted in its entirety in cassette E/F/GFS1.

INTRAOPERATIVE CONSULTATION: BFS,CFS,DFS: All negative for carcinoma
EFS,FFS,GFS: All negative for carcinoma

FINAL DIAGNOSIS:

A) Tongue, right, partial glossectomy: Moderately to poorly-differentiated, invasive squamous cell carcinoma, with the following features:

1. Size: 1.6 cm
2. Depth of invasion: 1.2 cm
3. Arising in a background of high-grade squamous intraepithelial neoplasia (carcinoma in-situ).
4. Lymphovascular invasion is not identified.
5. Margins: Invasive carcinoma extends no closer than 0.3 cm to the deep aspect of the posterior lateral margin, 0.4 cm to the deep aspect of the anterior medial margin, and 0.5 cm to the anterior lateral mucosal margin. All margins are free of in-situ carcinoma.
6. Minimum pathologic stage: pT1 NX MX (AJCC, 6th edition, 2002).

B-G) Tongue, anterior, lateral, posterior, medial, anterior deep, posterior deep, biopsies: No in-situ or invasive carcinoma identified.

Procedures used to establish the diagnosis: Routine

Source: NCI Genomic Data Commons file 3b195251-22ff-4522-9e29-b477ae377b1a (TCGA-P3-A5QA.D1AE6A5F-D46F-45F8-BFAE-6A9E0D1F7262.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).